Gene-level copy-number profile of tumor specimen TCGA-A7-A26E-01B from TCGA case TCGA-A7-A26E, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A7-A26E-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2b8ab526-01bc-4c93-b019-273a04d94c8c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A26E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/3ab0832f-de8d-48f3-8f35-4ba19289f604

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 546; copy number 2: 59,391; copy number 3: 245; copy number 4: 75; copy number 5: 5; copy number 6: 4; copy number 7: 3; copy number 8: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A26E-01A-11D-A275-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,569,324–26,600,739, 2 genes, copy number 5: AL121936.1, ABT1.
- chr6:158,296,671–158,303,372, 1 gene, copy number 5: AL360169.3.
- chr12:123,633,739–123,662,604, 3 genes, copy number 7 (within-gene range 2–7): GTF2H3, AC117503.3, AC117503.2.
- chr14:70,906,657–70,907,111, 1 gene, copy number 8: AC004825.2.
- chr15:25,054,210–25,062,427, 4 genes, copy number 6: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
